Somatic mutation profile of tumor specimen C3N-03490-02 (aliquot CPT0195680009) from CPTAC case C3N-03490, project CPTAC-3 (Base of tongue — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Base of tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.0 years (23,729 days).
Specimen C3N-03490-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f5b3057-5009-4482-ae43-6b0ad6b2f92c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03490-71 (Blood Derived Normal), aliquot CPT0195790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2714e1a-8fe8-44e7-a832-94ecf2be5541

The open-access MAF lists 148 somatic variants for this specimen: 99 protein-altering or splice-affecting, 26 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 26, Intron 12, Nonsense Mutation 7, Frame Shift Del 5, Splice Site 4, RNA 4, 5'UTR 3, 5'Flank 2, 3'UTR 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 184/379 reads (49%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHDC1 | c.4376C>T p.P1459L | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV55942359; called by muse, mutect2, varscan2
- AHNAK2 | c.5324C>T p.A1775V | Missense Mutation (SNP) | VAF 184/1014 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.362); catalogued as rs368943608; called by muse, mutect2, varscan2
- AL592490.1 | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 103/236 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs768094599, COSV69425078; called by muse, mutect2, varscan2
- ASIC2 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 29/97 reads (30%) | catalogued as rs1293768824; called by mutect2, varscan2
- ATXN7L1 | c.26C>A p.P9Q | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs762277618; called by muse, mutect2, varscan2
- C4orf33 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs149388613, COSV99829085; called by muse, mutect2, varscan2
- CNTN4 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV68575731, COSV68584026; called by muse, mutect2, varscan2
- COL4A1 | c.3637G>A p.G1213S | Missense Mutation (SNP) | VAF 227/436 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65423448; called by muse, mutect2, varscan2
- COL6A1 | c.2096G>A p.G699D | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as rs1241461198, COSV100719971; called by muse, mutect2, varscan2
- DIO2 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 108/300 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as COSV70445165; called by muse, mutect2, varscan2
- EFR3B | c.1714G>C p.A572P | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1446684731; called by muse, mutect2, varscan2
- ENPP2 | c.2166G>C p.K722N (on ENST00000075322 / NM_001040092.3; = p.K774N on NM_006209.5) | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.962); catalogued as COSV50037908; called by muse, mutect2, varscan2
- FAM166A | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV61116865; called by muse, mutect2
- FZD5 | c.1657G>A p.A553T | Missense Mutation (SNP) | VAF 38/212 reads (18%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.007); catalogued as rs752016971; called by muse, mutect2, varscan2
- GNPTAB | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54780011; called by muse, mutect2, varscan2
- GRAMD1A | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.821); catalogued as COSV58767906; called by muse, mutect2, varscan2
- JPH2 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 80/448 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs779505448, COSV65903209; called by muse, mutect2, varscan2
- KRT80 | c.835G>T p.E279* | Nonsense Mutation (SNP) | VAF 38/145 reads (26%) | catalogued as COSV100502842; called by muse, mutect2, varscan2
- NDNF | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs758772990, COSV65634468; called by muse, mutect2
- NHSL2 | c.1942C>T p.P648S (on ENST00000510661; = p.P1014S on NM_001013627.2) | Missense Mutation (SNP) | VAF 112/161 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768656059; called by muse, mutect2, varscan2
- OR2T6 | c.479C>T p.T160I | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs749587990; called by muse, mutect2, varscan2
- PEX5L | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 52/580 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55854470; called by muse, mutect2
- PLEKHM3 | c.47C>T p.T16M | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777343136, COSV66816434; called by muse, mutect2, varscan2
- PLXNA4 | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV58108670, COSV58168117; called by muse, mutect2, varscan2
- PTPRB | c.5228G>A p.R1743Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773098818; called by muse, mutect2, varscan2
- RNGTT | c.1720C>T p.R574* | Nonsense Mutation (SNP) | VAF 49/234 reads (21%) | catalogued as COSV55657544, COSV99667446; called by muse, mutect2, varscan2
- SHLD2 | c.1253G>T p.R418I | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as rs1439537524; called by mutect2, varscan2
- SIM1 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 31/154 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.947); catalogued as rs762305631, COSV53492558; called by muse, mutect2, varscan2
- SLC29A4 | c.448A>G p.I150V | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201270047; called by muse, mutect2, varscan2
- SLCO1C1 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs1287815056; called by muse, mutect2, varscan2
- SPG11 | c.6061C>T p.R2021W | Missense Mutation (SNP) | VAF 56/241 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs777943276, COSV55995077; called by muse, mutect2, varscan2
- TMEM119 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.366); catalogued as rs1285661091; called by muse, mutect2, varscan2
- TRIM50 | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 180/502 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.745); catalogued as rs782522740, COSV53093738; called by muse, mutect2, varscan2
- ADGB | c.2314A>T p.I772F | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALDH16A1 | c.289C>G p.P97A | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.763); called by muse, mutect2, varscan2
- AP2A2 | c.982C>A p.R328S | Missense Mutation (SNP) | VAF 100/180 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- APBA2 | c.508G>T p.D170Y | Missense Mutation (SNP) | VAF 138/590 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ATG7 | c.908G>A p.G303E | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, varscan2
- BIRC6 | c.10064C>G p.T3355S | Missense Mutation (SNP) | VAF 47/218 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- CHAF1B | c.781A>T p.N261Y | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- COL6A2 | c.579C>A p.N193K | Missense Mutation (SNP) | VAF 134/309 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CSTF2T | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 82/404 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CTNND2 | c.1247C>A p.P416Q | Missense Mutation (SNP) | VAF 155/629 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYTH4 | c.717G>C p.K239N | Missense Mutation (SNP) | VAF 56/316 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- DDX60 | c.1527T>G p.S509R | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- DNAH5 | c.9189C>A p.C3063* | Nonsense Mutation (SNP) | VAF 232/484 reads (48%) | called by muse, mutect2, varscan2
- ESCO1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAM71B | c.218G>T p.G73V | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- FLG2 | c.5657G>C p.S1886T | Missense Mutation (SNP) | VAF 78/401 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSD2 | c.2047_2049dup p.T683dup | In Frame Ins (INS) | VAF 16/78 reads (21%) | called by mutect2, pindel
- FYB2 | c.1346G>T p.C449F | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GCC2 | c.3523A>T p.K1175* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | called by muse, mutect2, varscan2
- GCKR | c.1067-1G>C p.X356_splice | Splice Site (SNP) | VAF 63/372 reads (17%) | called by muse, mutect2, varscan2
- GHR | c.859T>C p.F287L | Missense Mutation (SNP) | VAF 24/326 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.952); called by muse, mutect2
- GSTP1 | c.89A>T p.K30M | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2
- GUCY1A2 | c.1540G>C p.A514P | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, varscan2
- KEAP1 | c.1754del p.D585Afs*10 | Frame Shift Del (DEL) | VAF 78/243 reads (32%) | called by mutect2, pindel, varscan2
- KMT2D | c.3596_3597del p.L1199Hfs*7 | Frame Shift Del (DEL) | VAF 50/283 reads (18%) | called by pindel, varscan2
- LRRIQ3 | c.1714G>C p.V572L | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, varscan2
- MDGA2 | c.871A>T p.N291Y | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- MED14 | c.1893del p.G632Efs*10 | Frame Shift Del (DEL) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1417A>G p.R473G | Missense Mutation (SNP) | VAF 279/567 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- NCR2 | c.683G>C p.S228T | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NET1 | c.109G>C p.G37R | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NIPSNAP1 | c.106dup p.S36Ffs*5 | Frame Shift Ins (INS) | VAF 117/389 reads (30%) | called by mutect2, pindel, varscan2
- NPTXR | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 24/194 reads (12%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NSD1 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBSCN | c.21304G>C p.D7102H | Missense Mutation (SNP) | VAF 60/185 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- OSBPL7 | c.782A>C p.D261A | Missense Mutation (SNP) | VAF 115/351 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PCDH8 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 81/179 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PCDHA2 | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- PDLIM5 | c.1418A>T p.K473I | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- POTEC | c.1102del p.I368Sfs*12 | Frame Shift Del (DEL) | VAF 33/154 reads (21%) | called by mutect2, pindel, varscan2
- PPP1R15B | c.1144T>A p.S382T | Missense Mutation (SNP) | VAF 69/182 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- PRKDC | c.549A>C p.E183D | Missense Mutation (SNP) | VAF 17/120 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RNF44 | c.755del p.H252Pfs*21 | Frame Shift Del (DEL) | VAF 23/87 reads (26%) | called by mutect2, pindel, varscan2
- RYR2 | c.10839-2A>T p.X3613_splice | Splice Site (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- SHLD2 | c.1254A>T p.R418S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by mutect2, varscan2
- SLC16A10 | c.79G>C p.A27P | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, varscan2
- SLC17A2 | c.400C>A p.L134I | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- SMARCA4 | c.1438C>G p.L480V | Missense Mutation (SNP) | VAF 221/438 reads (50%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- SPDYA | c.382T>C p.Y128H | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TAS2R30 | c.909C>A p.D303E | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- THADA | c.1775G>T p.G592V | Missense Mutation (SNP) | VAF 54/257 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TKTL2 | c.1250T>G p.I417S | Missense Mutation (SNP) | VAF 78/320 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TMEM155 | c.294C>G p.H98Q | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- TMEM184B | c.393_406del p.Y131* | Nonsense Mutation (DEL) | VAF 111/669 reads (17%) | called by mutect2, pindel, varscan2
- TMEM248 | c.781-22_783del p.X261_splice | Splice Site (DEL) | VAF 11/69 reads (16%) | called by mutect2, pindel, varscan2
- TRIM44 | c.364G>C p.D122H | Missense Mutation (SNP) | VAF 55/310 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- TRMT61A | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 90/591 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- TRMT61A | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 90/587 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- UNC13C | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP53 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- VARS1 | c.2926-1G>T p.X976_splice | Splice Site (SNP) | VAF 55/203 reads (27%) | called by muse, mutect2, varscan2
- VWA5B2 | c.837C>A p.H279Q | Missense Mutation (SNP) | VAF 50/570 reads (9%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.829); called by muse, mutect2
- ZMYM2 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 59/182 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ZYG11A | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- ZZEF1 | c.5047C>T p.H1683Y | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ADGRL3 | c.1041A>G p.E347= (on ENST00000506720 / NM_001322402.2; = p.E279= on NM_015236.6) | Silent (SNP) | VAF 36/146 reads (25%) | called by muse, mutect2, varscan2
- ADGRV1 | c.879G>C p.L293= | Silent (SNP) | VAF 32/143 reads (22%) | called by muse, mutect2, varscan2
- ARHGAP24 | c.1395G>T p.L465= (on ENST00000395184 / NM_001025616.3; = p.L372= on NM_031305.3) | Silent (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- BDP1 | c.7377T>C p.N2459= | Silent (SNP) | VAF 40/208 reads (19%) | called by muse, mutect2, varscan2
- C7orf50 | c.357G>A p.Q119= | Silent (SNP) | VAF 25/216 reads (12%) | called by muse, varscan2
- FAM169A | c.1914G>A p.E638= | Silent (SNP) | VAF 133/285 reads (47%) | called by muse, mutect2, varscan2
- INPP4B | c.1218C>T p.N406= | Silent (SNP) | VAF 29/218 reads (13%) | called by muse, mutect2, varscan2
- KLRD1 | c.462G>A p.A154= | Silent (SNP) | VAF 19/114 reads (17%) | catalogued as rs139617485; called by muse, mutect2, varscan2
- LRRIQ3 | c.1689G>A p.K563= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV100598776, COSV100599620; called by muse, varscan2
- MAP6 | c.1032C>T p.A344= | Silent (SNP) | VAF 160/561 reads (29%) | catalogued as rs199708859; called by muse, mutect2, varscan2
- MED14 | c.2746C>T p.L916= | Silent (SNP) | VAF 97/295 reads (33%) | called by muse, mutect2, varscan2
- MUC22 | c.2736C>A p.G912= | Silent (SNP) | VAF 87/300 reads (29%) | called by muse, mutect2, varscan2
- NAALAD2 | c.288T>C p.D96= | Silent (SNP) | VAF 35/152 reads (23%) | called by muse, mutect2, varscan2
- NCKAP1L | c.2389C>T p.L797= | Silent (SNP) | VAF 54/203 reads (27%) | catalogued as rs779858287; called by muse, mutect2, varscan2
- OTOG | c.1731C>T p.D577= | Silent (SNP) | VAF 65/324 reads (20%) | called by muse, mutect2, varscan2
- PDE6B | c.1023C>T p.A341= | Silent (SNP) | VAF 155/657 reads (24%) | catalogued as COSV99727043; called by muse, mutect2, varscan2
- RTL9 | c.894C>G p.L298= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs1177841523, COSV71825333; called by muse, mutect2, varscan2
- SAMD9 | c.3034C>T p.L1012= | Silent (SNP) | VAF 105/254 reads (41%) | called by muse, mutect2, varscan2
- SKOR2 | c.2292C>T p.D764= | Silent (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- SMTN | c.2538C>T p.F846= | Silent (SNP) | VAF 60/620 reads (10%) | catalogued as rs371780875; called by muse, mutect2
- SPHKAP | c.3903C>A p.I1301= | Silent (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2, varscan2
- TLCD2 | c.357C>T p.L119= | Silent (SNP) | VAF 22/85 reads (26%) | called by muse, mutect2, varscan2
- TNIK | c.912C>T p.D304= | Silent (SNP) | VAF 28/235 reads (12%) | catalogued as rs933112241; called by muse, mutect2, varscan2
- TNN | c.636C>T p.C212= | Silent (SNP) | VAF 98/461 reads (21%) | catalogued as COSV99513077; called by muse, mutect2, varscan2
- TPI1 | c.105C>T p.S35= | Silent (SNP) | VAF 46/367 reads (13%) | catalogued as rs1282208297, COSV57536646; called by muse, mutect2, varscan2
- UNC5C | c.1185A>G p.V395= | Silent (SNP) | VAF 39/179 reads (22%) | called by muse, mutect2, varscan2
- AC114490.3 | c.*689G>A | 3'UTR (SNP) | VAF 70/339 reads (21%) | catalogued as rs1251123937; called by muse, mutect2, varscan2
- AC136628.2 | n.553C>T | RNA (SNP) | VAF 82/337 reads (24%) | called by muse, mutect2, varscan2
- ARHGAP23P1 | chr16:33938592 C>G | 5'Flank (SNP) | VAF 78/218 reads (36%) | called by muse, mutect2, varscan2
- CDH6 | c.1882+39A>C | Intron (SNP) | VAF 58/374 reads (16%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.2107-53A>G | Intron (SNP) | VAF 55/134 reads (41%) | called by muse, mutect2, varscan2
- CMA1 | chr14:24501672 T>C | 3'Flank (SNP) | VAF 55/315 reads (17%) | catalogued as rs1403641170; called by muse, mutect2, varscan2
- COPZ1 | c.-31G>A | 5'UTR (SNP) | VAF 49/284 reads (17%) | called by muse, mutect2, varscan2
- DCHS2 | n.888C>T | RNA (SNP) | VAF 13/98 reads (13%) | catalogued as COSV59734284; called by muse, mutect2, varscan2
- DEPDC1 | c.911-433G>T | Intron (SNP) | VAF 39/75 reads (52%) | called by muse, mutect2, varscan2
- ENTPD1 | chr10:95755715 A>T | 5'Flank (SNP) | VAF 38/156 reads (24%) | called by muse, mutect2, varscan2
- FLII | c.63+142C>T | Intron (SNP) | VAF 97/203 reads (48%) | called by muse, mutect2, varscan2
- GGH | c.360+18C>A | Intron (SNP) | VAF 24/327 reads (7%) | called by muse, mutect2
- LINC00602 | n.1217C>G | RNA (SNP) | VAF 44/197 reads (22%) | called by muse, mutect2, varscan2
- MFN2 | c.2070-15C>G | Intron (SNP) | VAF 116/694 reads (17%) | called by muse, varscan2
- NUB1 | c.-48G>C | 5'UTR (SNP) | VAF 20/118 reads (17%) | called by muse, varscan2
- POLR1C | c.-13G>A | 5'UTR (SNP) | VAF 100/464 reads (22%) | catalogued as rs1561855472; called by muse, mutect2, varscan2
- POM121L4P | n.899C>T | RNA (SNP) | VAF 245/1464 reads (17%) | called by muse, mutect2, varscan2
- RBCK1 | c.167+482G>C | Intron (SNP) | VAF 38/231 reads (16%) | called by muse, mutect2, varscan2
- SGK1 | c.286-7623A>G | Intron (SNP) | VAF 47/101 reads (47%) | catalogued as rs1189438610; called by muse, mutect2, varscan2
- SLC39A4 | c.1474+22G>C | Intron (SNP) | VAF 154/726 reads (21%) | called by muse, mutect2, varscan2
- SNX29 | c.1402+9189C>G | Intron (SNP) | VAF 21/238 reads (9%) | catalogued as rs1320747760; called by muse, mutect2
- TPM1 | c.115-270G>A | Intron (SNP) | VAF 165/665 reads (25%) | called by muse, mutect2, varscan2
- UTRN | c.7479+6296A>G | Intron (SNP) | VAF 17/29 reads (59%) | called by muse, mutect2, varscan2
